Somatic mutation profile of tumor specimen TCGA-A3-3385-01A (aliquot TCGA-A3-3385-01A-02D-1421-08) from TCGA case TCGA-A3-3385, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.9 years (17,114 days).
Specimen TCGA-A3-3385-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac39027a-cbd9-461a-b836-05c2fa835daf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3385-11A (Solid Tissue Normal), aliquot TCGA-A3-3385-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ad818e8-ba33-46da-9d0c-e98923a63fb6

The open-access MAF lists 62 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 11, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEND6 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV66068731; called by muse, mutect2, varscan2
- CAPN7 | c.2306T>A p.F769Y | Missense Mutation (SNP) | VAF 108/307 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.251); catalogued as COSV53743811; called by muse, mutect2, varscan2
- CWC22 | c.196A>T p.M66L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1461952597, COSV55427994, COSV99844750; called by muse, varscan2
- DDX59 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58751502; called by muse, mutect2, varscan2
- DPP10 | c.669T>A p.F223L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.364); catalogued as COSV59680319; called by muse, mutect2, varscan2
- DPP10 | c.670A>C p.N224H | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59680344; called by muse, mutect2, varscan2
- EPB41L2 | c.2546T>G p.V849G | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); catalogued as COSV61354684; called by muse, mutect2, varscan2
- ERBB2 | c.1946G>C p.S649T | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.141); catalogued as COSV54068190; called by muse, mutect2, varscan2
- FGFR1 | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV58332577; called by muse, mutect2, varscan2
- GPR4 | c.277T>A p.F93I | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV59916708; called by muse, mutect2, varscan2
- GTF2A1 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53336830; called by muse, mutect2, varscan2
- HACE1 | c.2344-1G>T p.X782_splice | Splice Site (SNP) | VAF 41/102 reads (40%) | catalogued as COSV53499196; called by muse, mutect2, varscan2
- KHDC3L | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as rs866082650, COSV64859035; called by muse, mutect2, varscan2
- LAMA2 | c.4343G>C p.C1448S | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70344676; called by muse, mutect2, varscan2
- LCA5 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 57/133 reads (43%) | catalogued as COSV63971153; called by muse, mutect2, varscan2
- LMBRD2 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56949475; called by muse, mutect2, varscan2
- MAP7D2 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 98/262 reads (37%) | catalogued as COSV65526701; called by muse, mutect2, varscan2
- MIDN | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1333492951, COSV56294789; called by muse, mutect2, varscan2
- MSH2 | c.2119T>C p.C707R | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV51878098; called by muse, mutect2, varscan2
- MYH2 | c.648+2T>A p.X216_splice | Splice Site (SNP) | VAF 38/101 reads (38%) | catalogued as COSV55435823; called by muse, mutect2, varscan2
- NCOR2 | c.2183G>A p.G728E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.739); catalogued as COSV62296639; called by muse, mutect2, varscan2
- NDRG2 | c.789C>A p.D263E (on ENST00000298687 / NM_001354570.1; = p.D249E on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs926881305, COSV53872248; called by muse, mutect2, varscan2
- NLRP10 | c.1360T>G p.L454V | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV60779925; called by muse, mutect2, varscan2
- NOTCH3 | c.1669G>T p.G557C | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317994194, COSV54632301; called by muse, mutect2, varscan2
- OR2T33 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763180162, COSV100532096; called by muse, mutect2, varscan2
- PCDHGB4 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 127/474 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53930591; called by muse, mutect2, varscan2
- PENK | c.774A>C p.E258D | Missense Mutation (SNP) | VAF 134/259 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV59240939; called by muse, mutect2, varscan2
- PRRG3 | c.144A>T p.E48D | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV64850948; called by muse, mutect2, varscan2
- RICTOR | c.2579G>A p.G860D | Missense Mutation (SNP) | VAF 205/352 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV57120635; called by muse, mutect2, varscan2
- RTL6 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs955069649, COSV57979524; called by muse, mutect2, varscan2
- SPHKAP | c.4198G>C p.D1400H | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV60875527; called by muse, mutect2, varscan2
- STRIP1 | c.1432A>C p.I478L | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV63930488; called by muse, mutect2, varscan2
- SVIL | c.5291A>G p.Y1764C (on ENST00000355867 / NM_021738.3; = p.Y1338C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63442483; called by muse, mutect2, varscan2
- TFEC | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 117/408 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.354); catalogued as COSV55399788; called by muse, mutect2, varscan2
- TGFBRAP1 | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV51511411; called by muse, mutect2, varscan2
- TIMM17A | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66170913; called by muse, mutect2, varscan2
- TNK1 | c.1762G>A p.D588N (on ENST00000576812 / NM_001251902.2; = p.D583N on NM_003985.5) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.985); catalogued as rs750427809, COSV61170464, COSV61170730; called by muse, mutect2, varscan2
- TPPP | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV62191778; called by muse, mutect2, varscan2
- TUBB1 | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 125/216 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53886478; called by muse, mutect2, varscan2
- ZCCHC12 | c.1091G>T p.S364I | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV59571369, COSV59571405, COSV59572026; called by muse, mutect2, varscan2
- ZEB2 | c.1404C>A p.D468E | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1443743088, COSV57955306; called by muse, mutect2, varscan2
- ZFAND1 | c.391T>C p.W131R | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55107414; called by muse, mutect2, varscan2
- ZFP82 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67565098; called by muse, mutect2, varscan2
- GPR174 | c.721del p.I241Ffs*12 | Frame Shift Del (DEL) | VAF 76/219 reads (35%) | called by mutect2, pindel, varscan2
- HMGXB4 | c.247del p.Y83Tfs*31 | Frame Shift Del (DEL) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- KIF13B | c.1284del p.Q428Hfs*24 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- MPC1 | c.306-2del p.X102_splice | Splice Site (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- SIRT1 | c.1986dup p.D663Rfs*2 | Frame Shift Ins (INS) | VAF 74/220 reads (34%) | called by mutect2, pindel, varscan2
- SLC6A17 | c.156_157del p.E53Gfs*13 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- ZSCAN21 | c.737del p.N246Mfs*240 | Frame Shift Del (DEL) | VAF 51/216 reads (24%) | called by mutect2, pindel, varscan2
- ASH1L | c.8538C>G p.R2846= (on ENST00000368346 / NM_001366177.2; = p.R2841= on NM_018489.3) | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as COSV64207184; called by muse, mutect2, varscan2
- BAZ1B | c.1059G>C p.V353= | Silent (SNP) | VAF 105/210 reads (50%) | catalogued as COSV59990443; called by muse, mutect2, varscan2
- CCDC9B | c.993G>A p.K331= | Silent (SNP) | VAF 72/180 reads (40%) | catalogued as COSV66875192; called by muse, mutect2, varscan2
- DEPDC4 | c.100C>T p.L34= | Silent (SNP) | VAF 88/208 reads (42%) | catalogued as COSV54553491; called by muse, mutect2, varscan2
- HERPUD2 | c.519G>T p.G173= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as rs976158499, COSV60944755; called by muse, mutect2, varscan2
- NIPBL | c.3924G>A p.A1308= | Silent (SNP) | VAF 59/200 reads (30%) | catalogued as rs367925827, COSV99243209; called by muse, mutect2, varscan2
- TBX19 | c.672C>T p.H224= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV63197235; called by muse, mutect2, varscan2
- TRAPPC13 | c.252C>T p.I84= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs993256120, COSV51557227; called by muse, mutect2, varscan2
- VPS54 | c.486A>T p.V162= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as COSV55440014; called by muse, mutect2, varscan2
- ZDHHC8 | c.441C>A p.R147= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV57709832; called by muse, mutect2, varscan2
- ZNF260 | c.390T>C p.H130= | Silent (SNP) | VAF 184/440 reads (42%) | catalogued as COSV72951191; called by muse, mutect2, varscan2
- SCARB1 | c.1651+3378T>C | Intron (SNP) | VAF 77/172 reads (45%) | catalogued as COSV55546540; called by muse, mutect2, varscan2
